Somatic mutation profile of tumor specimen 0DRQT1 from CCDI case PBCGYP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 17.4 years (6,343 days).
Specimen 0DRQT1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d952749b-02e8-4450-b871-9d62ce829efd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRQSP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/978b3f46-1919-4e4c-b13b-f535fd632c69

The open-access MAF lists 12,360 somatic variants for this specimen: 7,683 protein-altering or splice-affecting, 2,378 silent, 2,299 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6,835, Silent 2,378, Intron 1,338, 3'UTR 527, Nonsense Mutation 376, 5'UTR 264, Splice Site 174, Splice Region 141, Frame Shift Ins 114, 5'Flank 66, RNA 59, 3'Flank 45.

Variants (750 of 12,360; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVRL1 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 248/636 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28936401, CD050129, CM970049, COSV66361224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASS1 | c.566+1G>T p.X189_splice | Splice Site (SNP) | VAF 141/442 reads (32%) | catalogued as rs1057520659, COSV61690693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 329/960 reads (34%) | catalogued as rs587779815, CM960098, COSV53734748; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.6615G>A p.W2205* | Nonsense Mutation (SNP) | VAF 447/1217 reads (37%) | catalogued as rs1555119041; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP8B1 | c.2599C>T p.R867C | Missense Mutation (SNP) | VAF 225/539 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909103, CM051851, COSV99377491; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLMP | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 252/652 reads (39%) | catalogued as rs587776966, CM121566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 184/480 reads (38%) | catalogued as rs768345097, CM050551, COSV60686900; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.13338del p.A4447Lfs*16 | Frame Shift Del (DEL) | VAF 287/971 reads (30%) | catalogued as rs1554017211; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DNMT3A | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 234/692 reads (34%) | catalogued as rs779626155, COSV53041751, COSV53073691; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ETFB | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 201/548 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs548046212, COSV58537541; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.8038C>T p.R2680C | Missense Mutation (SNP) | VAF 194/501 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs794728283, CM930248, COSV100355798; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 384/1138 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLDC | c.2838+5G>A | Splice Region (SNP) | VAF 203/541 reads (38%) | catalogued as rs386833568, CS062057; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MMUT | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 81/1460 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs483352778, CM012405, COSV51273783, COSV51277513; ClinVar: not provided / pathogenic; called by muse, mutect2
- MYH6 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 320/888 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs753444140; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NLRP7 | c.2471+1G>A p.X824_splice (on ENST00000340844 / NM_206828.3; = p.X796_splice on NM_139176.3) | Splice Site (SNP) | VAF 185/548 reads (34%) | catalogued as rs104895505, CS061310, COSV60178990; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIGT | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 264/683 reads (39%) | catalogued as rs199968454, COSV54125906; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PMPCA | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 140/402 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs573267388, COSV65508950; ClinVar: pathogenic; called by muse, varscan2
- PNPO | c.545G>A p.R182H (on ENST00000225573; = p.R225H on NM_018129.4) | Missense Mutation (SNP) | VAF 220/534 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550423482, CM130377, CM144462; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2103G>A p.W701* | Nonsense Mutation (SNP) | VAF 341/914 reads (37%) | catalogued as rs772842361, CM133229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RNF31 | c.2480G>A p.R827H | Missense Mutation (SNP) | VAF 140/408 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.945); catalogued as rs377035972; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC39A4 | c.599C>T p.P200L (on ENST00000301305 / NM_001374839.1; = p.P175L on NM_017767.3) | Missense Mutation (SNP) | VAF 148/446 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs121434287, CM021338; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SPTB | c.5266C>T p.R1756* | Nonsense Mutation (SNP) | VAF 189/425 reads (44%) | catalogued as rs267607086, CM094379; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFB2 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 827/1587 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs869312903, CM126583; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TOP3A | c.2271dup p.R758Qfs*3 | Frame Shift Ins (INS) | VAF 147/378 reads (39%) | catalogued as rs752838075; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 149/353 reads (42%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 248/742 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- TSHR | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 219/589 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772490052, COSV53315668; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- VWF | c.2279G>A p.R760H | Missense Mutation (SNP) | VAF 140/392 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs61748467, CM095392, COSV99779085; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 378/979 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs1340993736, COSV57923752; called by muse, mutect2, varscan2
- AARS2 | c.2476C>T p.R826* | Nonsense Mutation (SNP) | VAF 128/326 reads (39%) | catalogued as rs759299855; called by muse, varscan2
- AARS2 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 240/638 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs141973247; called by muse, varscan2
- AARS2 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 305/838 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99771662; called by muse, mutect2, varscan2
- AATK | c.3364G>T p.G1122* (on ENST00000326724 / NM_001080395.3; = p.G1019* on NM_004920.2) | Nonsense Mutation (SNP) | VAF 221/625 reads (35%) | catalogued as COSV100352881, COSV58364979; called by muse, mutect2, varscan2
- ABAT | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 252/658 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762137050, COSV51621604; called by muse, mutect2, varscan2
- ABCA10 | c.3196A>C p.T1066P | Missense Mutation (SNP) | VAF 264/621 reads (43%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.53); catalogued as COSV52221666; called by muse, mutect2, varscan2
- ABCA2 | c.2744C>T p.P915L (on ENST00000614293; = p.P885L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 145/440 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1445942515; called by muse, mutect2, varscan2
- ABCA2 | c.1441G>A p.V481M (on ENST00000614293; = p.V451M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 192/523 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs369407867, COSV55804937; called by muse, mutect2, varscan2
- ABCA4 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 306/854 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs138359497, COSV99058787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA5 | c.128dup p.L43Ffs*8 | Frame Shift Ins (INS) | VAF 140/472 reads (30%) | catalogued as rs751512043; called by mutect2, varscan2
- ABCB10 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 1049/1921 reads (55%) | catalogued as rs1370648698; called by muse, mutect2, varscan2
- ABCB11 | c.2737T>G p.L913V | Missense Mutation (SNP) | VAF 288/826 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.3); catalogued as COSV55588303; called by mutect2, varscan2
- ABCB11 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 287/788 reads (36%) | catalogued as COSV55587613; called by muse, mutect2, varscan2
- ABCB5 | c.3124C>T p.R1042* (on ENST00000404938 / NM_001163941.2; = p.R597* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 440/1109 reads (40%) | catalogued as rs201925737; called by muse, mutect2, varscan2
- ABCC10 | c.1328G>A p.R443H (on ENST00000372530 / NM_001198934.2; = p.R400H on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 296/791 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs758290484, COSV55092100; called by muse, mutect2, varscan2
- ABCC11 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 258/694 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs201784880, COSV100750707; called by muse, mutect2, varscan2
- ABCC12 | c.2732G>A p.R911H | Missense Mutation (SNP) | VAF 348/942 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1329090766; called by muse, varscan2
- ABCC2 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 410/1028 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144390464; ClinVar: uncertain significance; called by muse, varscan2
- ABCC2 | c.1834C>T p.R612W | Missense Mutation (SNP) | VAF 223/599 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777791701; called by muse, mutect2, varscan2
- ABCC3 | c.3833G>A p.R1278H | Missense Mutation (SNP) | VAF 207/589 reads (35%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.911); catalogued as rs759534433, COSV53319352; called by muse, mutect2, varscan2
- ABCC5 | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 245/647 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs368112213; called by muse, mutect2, varscan2
- ABCC9 | c.4205C>A p.S1402Y | Missense Mutation (SNP) | VAF 448/1208 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as CM141611, COSV53976423, COSV99684967; called by mutect2, varscan2
- ABCD4 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 140/361 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs375098533, COSV53992663; called by muse, mutect2, varscan2
- ABCD4 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 250/571 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.148); catalogued as rs138755259; called by muse, mutect2, varscan2
- ABCF3 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 135/521 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1301386278, COSV53054426; called by muse, mutect2, varscan2
- ABCG2 | c.882C>A p.F294L | Missense Mutation (SNP) | VAF 325/1005 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.335); catalogued as COSV52944467; called by muse, mutect2, varscan2
- ABHD4 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 200/702 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.733); catalogued as rs1243186430; called by muse, mutect2, varscan2
- ABI3BP | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 262/749 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52544627; called by muse, mutect2, varscan2
- ABR | c.1294C>T p.R432W (on ENST00000302538 / NM_021962.5; = p.R395W on NM_001092.5) | Missense Mutation (SNP) | VAF 169/521 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs200250455, COSV52144171; called by muse, mutect2, varscan2
- ABRAXAS2 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 436/1233 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.877); catalogued as COSV53717177; called by muse, mutect2, varscan2
- ABRAXAS2 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 351/966 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV53718175; called by muse, mutect2, varscan2
- ABT1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 272/796 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1336640036; called by muse, mutect2, varscan2
- AC004593.2 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 248/707 reads (35%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as rs368209645, COSV56090416; called by muse, varscan2
- AC008397.2 | c.1769C>T p.T590M | Missense Mutation (SNP) | VAF 108/378 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755896777; called by muse, mutect2, varscan2
- AC008397.2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 84/221 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as rs767249358, COSV62748376; called by muse, mutect2, varscan2
- AC092143.1 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 260/644 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs1229540455, COSV59249353; called by muse, mutect2, varscan2
- AC110285.1 | n.1853-4G>A | Splice Region (SNP) | VAF 121/318 reads (38%) | catalogued as rs574957477; called by muse, mutect2, varscan2
- ACAA1 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 215/573 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755386041; called by muse, mutect2, varscan2
- ACACB | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 213/586 reads (36%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.951); catalogued as rs781305786; called by muse, mutect2, varscan2
- ACADVL | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 147/398 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767849841, COSV50035667; called by muse, mutect2, varscan2
- ACAP3 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 122/396 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV57639883; called by muse, mutect2, varscan2
- ACHE | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as rs1343315644, COSV99574532; called by muse, varscan2
- ACHE | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 157/399 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs1187607195; called by muse, mutect2, varscan2
- ACOX3 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 295/861 reads (34%) | catalogued as rs545024479, COSV62711330; called by muse, mutect2, varscan2
- ACSBG2 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 231/574 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99397238; called by mutect2, varscan2
- ACSF3 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 114/362 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs901081235; ClinVar: uncertain significance; called by muse, varscan2
- ACSL5 | c.1119C>A p.F373L (on ENST00000354273; = p.F429L on NM_016234.3) | Missense Mutation (SNP) | VAF 443/1131 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1166042644, COSV100634717, COSV61129645; called by muse, mutect2, varscan2
- ACSM3 | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 409/1008 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs776152834; called by muse, mutect2, varscan2
- ACSS1 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 274/759 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.156); catalogued as rs775016558, COSV60222349; called by muse, mutect2, varscan2
- ACTN2 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 240/869 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as rs779702876; called by muse, mutect2, varscan2
- ACTN3 | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 212/551 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.363); catalogued as COSV101557884; called by muse, mutect2, varscan2
- ACTN4 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 122/334 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs756003995; ClinVar: uncertain significance; called by muse, varscan2
- ACTN4 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 140/348 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs1178103660; called by muse, varscan2
- ACTR8 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 50/1498 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1000438448, COSV51635578; called by muse, mutect2
- ACYP2 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 235/448 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV57816875; called by muse, mutect2, varscan2
- ADAM10 | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 504/1351 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs144764887, COSV53049724; called by muse, mutect2, varscan2
- ADAM20 | c.1554T>G p.I518M | Missense Mutation (SNP) | VAF 172/443 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99833403; called by muse, mutect2, varscan2
- ADAM21 | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 248/739 reads (34%) | catalogued as COSV50788856; called by muse, mutect2, varscan2
- ADAM28 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 292/780 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1223900411, COSV99738336; called by muse, mutect2, varscan2
- ADAM32 | c.1525G>T p.G509C | Missense Mutation (SNP) | VAF 300/709 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1345356198; called by muse, mutect2, varscan2
- ADAM7 | c.1771A>C p.T591P | Missense Mutation (SNP) | VAF 377/1118 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV51541698, COSV99444989; called by muse, mutect2, varscan2
- ADAM8 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs1436903805; called by muse, mutect2, varscan2
- ADAMTS10 | c.2335C>T p.R779* | Nonsense Mutation (SNP) | VAF 152/423 reads (36%) | catalogued as COSV54351845; called by muse, mutect2, varscan2
- ADAMTS18 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 375/954 reads (39%) | catalogued as rs1011453043, COSV51400271; called by muse, mutect2, varscan2
- ADAMTS19 | c.1550T>C p.I517T | Missense Mutation (SNP) | VAF 484/1341 reads (36%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.786); catalogued as rs544559514, COSV99176237; called by muse, mutect2, varscan2
- ADAMTS2 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 150/446 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as rs148737005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS20 | c.3131G>A p.R1044Q | Missense Mutation (SNP) | VAF 285/842 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777369534, COSV67133581; called by muse, varscan2
- ADAMTS3 | c.770A>C p.N257T | Missense Mutation (SNP) | VAF 386/1000 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.679); catalogued as COSV54393282; called by muse, mutect2, varscan2
- ADAMTS7 | c.4775G>A p.R1592H | Missense Mutation (SNP) | VAF 162/675 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763966802, COSV101183309; called by muse, mutect2
- ADAMTS9 | c.4039G>A p.G1347R | Missense Mutation (SNP) | VAF 291/786 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190815128, COSV99900517; called by muse, varscan2
- ADAMTSL4 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 131/542 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199762322; called by muse, mutect2, varscan2
- ADAP1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 229/669 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.115); catalogued as rs769811232; called by muse, mutect2, varscan2
- ADAP1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 237/708 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as rs200025782; called by muse, mutect2, varscan2
- ADAR | c.3095G>A p.R1032H | Missense Mutation (SNP) | VAF 379/684 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs773129591; ClinVar: uncertain significance; called by muse, varscan2
- ADAR | c.2668+2T>C p.X890_splice | Splice Site (SNP) | VAF 291/1070 reads (27%) | catalogued as CS051677; called by muse, mutect2, varscan2
- ADARB1 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 200/587 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as rs866335248; called by muse, mutect2, varscan2
- ADARB2 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 80/171 reads (47%) | catalogued as COSV67213562; called by muse, mutect2, varscan2
- ADARB2 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 120/360 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67240066; called by muse, mutect2, varscan2
- ADCK2 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 317/794 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs968462082; called by muse, mutect2, varscan2
- ADCY2 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 251/703 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs143227108; called by muse, mutect2, varscan2
- ADCY3 | c.3077C>T p.T1026M | Missense Mutation (SNP) | VAF 166/484 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as rs200335673, COSV53164474; called by muse, varscan2
- ADCY7 | c.2836G>A p.A946T | Missense Mutation (SNP) | VAF 199/556 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139215312; called by muse, mutect2, varscan2
- ADCY8 | c.2032C>T p.R678W | Missense Mutation (SNP) | VAF 392/1020 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs759481208, COSV53907807; called by muse, varscan2
- ADGB | c.3767T>C p.I1256T | Missense Mutation (SNP) | VAF 373/965 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs1362402426; called by muse, mutect2, varscan2
- ADGRA2 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 449/1279 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781535229, COSV99605071; called by muse, mutect2, varscan2
- ADGRB1 | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 100/287 reads (35%) | catalogued as COSV60099409; called by muse, mutect2, varscan2
- ADGRB2 | c.3235G>A p.A1079T | Missense Mutation (SNP) | VAF 230/612 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776439402; called by muse, mutect2, varscan2
- ADGRB2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 187/473 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779927149, COSV99926623; called by muse, mutect2, varscan2
- ADGRB2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 110/304 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs753123086; called by muse, mutect2, varscan2
- ADGRF1 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 547/1435 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143178573, COSV51947538; called by muse, mutect2, varscan2
- ADGRG4 | c.7841C>T p.T2614M | Missense Mutation (SNP) | VAF 391/516 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1161020084, COSV99794540; called by muse, mutect2, varscan2
- ADGRL2 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 407/1053 reads (39%) | catalogued as COSV54678528; called by muse, mutect2, varscan2
- ADGRL2 | c.3625G>T p.G1209* | Nonsense Mutation (SNP) | VAF 363/1022 reads (36%) | catalogued as COSV54690536; called by muse, mutect2, varscan2
- ADGRL3 | c.3134A>G p.H1045R (on ENST00000506720 / NM_001322402.2; = p.H977R on NM_015236.6) | Missense Mutation (SNP) | VAF 409/1200 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.871); catalogued as rs1472078705; called by muse, mutect2, varscan2
- ADM2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 132/321 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.061); catalogued as rs747277520; called by muse, varscan2
- ADO | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 122/290 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.897); catalogued as rs764835246; called by muse, mutect2, varscan2
- ADRB3 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 158/396 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61461861; called by muse, mutect2, varscan2
- ADSL | c.862+5G>A | Splice Region (SNP) | VAF 274/819 reads (33%) | catalogued as COSV53407789; called by muse, mutect2, varscan2
- ADSS1 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 108/382 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772909262; called by muse, mutect2, varscan2
- AFAP1L2 | c.1516G>A p.V506M | Missense Mutation (SNP) | VAF 276/740 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369541262; called by muse, mutect2, varscan2
- AFG3L2 | c.2308A>G p.T770A | Missense Mutation (SNP) | VAF 304/813 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs745988988; called by muse, mutect2, varscan2
- AFM | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 300/937 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as rs771719904, COSV56919283, COSV56920023; called by muse, mutect2, varscan2
- AGAP6 | c.1406T>C p.L469S (on ENST00000374056 / NM_001365867.1; = p.L492S on NM_001077665.2) | Missense Mutation (SNP) | VAF 126/628 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554865143; called by muse, varscan2
- AGAP6 | c.1910C>T p.A637V (on ENST00000374056 / NM_001365867.1; = p.A660V on NM_001077665.2) | Missense Mutation (SNP) | VAF 50/424 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1265928178, COSV65018027; called by muse, mutect2
- AGK | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 471/1141 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs566563726; called by muse, mutect2, varscan2
- AGL | c.3508A>G p.N1170D | Missense Mutation (SNP) | VAF 379/1067 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1236655933; called by muse, mutect2, varscan2
- AGO1 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 218/536 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100940963; called by muse, mutect2, varscan2
- AGPAT3 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 281/910 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.611); catalogued as rs773520142; called by muse, mutect2, varscan2
- AGPAT4 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 250/750 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201134001, COSV57243548; called by muse, mutect2, varscan2
- AGRP | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 268/667 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs769667707; called by muse, mutect2, varscan2
- AGTPBP1 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 373/1028 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs199637681; called by muse, mutect2, varscan2
- AGTR1 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 541/1368 reads (40%) | catalogued as rs768866306; called by muse, mutect2, varscan2
- AHCTF1 | c.109C>T p.R37* (on ENST00000366508; = p.R11* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 208/864 reads (24%) | catalogued as rs866640499, COSV100403238; called by muse, mutect2, varscan2
- AHCYL1 | c.477G>A p.A159= | Splice Region (SNP) | VAF 228/601 reads (38%) | catalogued as COSV100779699; called by muse, mutect2, varscan2
- AHI1 | c.3220C>T p.R1074C | Missense Mutation (SNP) | VAF 393/1140 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs751078274, COSV99661767; called by muse, mutect2, varscan2
- AHI1 | c.2260A>G p.T754A | Missense Mutation (SNP) | VAF 346/886 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs752392677; called by muse, mutect2, varscan2
- AHR | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 625/1607 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV54124426; called by muse, mutect2, varscan2
- AHSG | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 274/694 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374953444; called by muse, mutect2, varscan2
- AIF1L | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 145/373 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1166316938; called by muse, mutect2, varscan2
- AK9 | c.1372C>A p.L458I | Missense Mutation (SNP) | VAF 330/873 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.177); catalogued as rs749464829; called by muse, mutect2, varscan2
- AK9 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 249/819 reads (30%) | catalogued as rs201060409, COSV53424497; called by muse, mutect2, varscan2
- AKAP11 | c.4391G>T p.S1464I | Missense Mutation (SNP) | VAF 580/1525 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as COSV99213818; called by muse, mutect2, varscan2
- AKAP11 | c.5462C>T p.T1821M | Missense Mutation (SNP) | VAF 80/952 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.497); catalogued as rs138710307; called by muse, mutect2
- AKAP13 | c.2626G>A p.A876T | Missense Mutation (SNP) | VAF 208/478 reads (44%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.041); catalogued as rs747706132; called by muse, mutect2, varscan2
- AKAP13 | c.6598C>T p.R2200C (on ENST00000394518 / NM_007200.5; = p.R2204C on NM_006738.6) | Missense Mutation (SNP) | VAF 319/874 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63450117; called by muse, mutect2, varscan2
- AKAP13 | c.7843C>T p.R2615W (on ENST00000394518 / NM_007200.5; = p.R2619W on NM_006738.6) | Missense Mutation (SNP) | VAF 132/370 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1325948576; called by muse, varscan2
- AKAP13 | c.7909C>T p.R2637W (on ENST00000394518 / NM_007200.5; = p.R2641W on NM_006738.6) | Missense Mutation (SNP) | VAF 133/326 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs758809249, COSV100774746; called by muse, varscan2
- AKAP3 | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 252/611 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs145618639, COSV57415831; called by muse, mutect2, varscan2
- AKAP6 | c.3424C>T p.R1142* | Nonsense Mutation (SNP) | VAF 337/962 reads (35%) | catalogued as COSV55222637; called by muse, mutect2, varscan2
- AKAP6 | c.6047C>T p.A2016V | Missense Mutation (SNP) | VAF 435/1203 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV55215920; called by muse, mutect2, varscan2
- AKNA | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 145/412 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as rs200448078; called by muse, mutect2, varscan2
- AKNAD1 | c.2174dup p.L725Ffs*17 | Frame Shift Ins (INS) | VAF 350/1086 reads (32%) | catalogued as rs779266259; called by pindel, varscan2
- AKR1D1 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 394/1030 reads (38%) | catalogued as rs749224036, CM097184, COSV54341071; called by muse, mutect2, varscan2
- AKT1 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 128/339 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs762559261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALCAM | c.1420A>G p.I474V | Missense Mutation (SNP) | VAF 345/980 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as rs918687551; called by muse, mutect2, varscan2
- ALDH1A3 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 272/708 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as rs770610190; called by muse, mutect2, varscan2
- ALDH1B1 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 220/668 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as rs763516924; called by muse, mutect2, varscan2
- ALKBH3 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 220/648 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs769039712, COSV57022547; called by muse, mutect2, varscan2
- ALKBH7 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 114/323 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as rs1248956794; called by muse, mutect2, varscan2
- ALKBH7 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 132/387 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755922067, COSV55532649, COSV55532815; called by muse, mutect2
- ALKBH8 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 324/831 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.661); catalogued as COSV52837289; called by muse, mutect2, varscan2
- ALOXE3 | c.362T>G p.I121S | Missense Mutation (SNP) | VAF 169/496 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV59075619; called by muse, mutect2, varscan2
- ALPK1 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 344/928 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.919); catalogued as rs747393894, COSV51583869; called by muse, mutect2, varscan2
- ALPK3 | c.1916C>T p.T639M | Missense Mutation (SNP) | VAF 140/482 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs151054715; called by muse, mutect2, varscan2
- AMIGO3 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 207/473 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1237596292, COSV57539411; called by muse, mutect2, varscan2
- AMOTL1 | c.2366G>A p.R789H | Missense Mutation (SNP) | VAF 299/802 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772651219; called by muse, mutect2, varscan2
- AMOTL2 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 217/526 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.207); catalogued as rs368196162; called by muse, mutect2, varscan2
- AMPD3 | c.148G>A p.G50R (on ENST00000396553 / NM_001025389.2; = p.G59R on NM_000480.3) | Missense Mutation (SNP) | VAF 348/1005 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); catalogued as rs774226348, COSV101158302; called by muse, mutect2, varscan2
- AMPD3 | c.1208A>G p.D403G (on ENST00000396553 / NM_001025389.2; = p.D412G on NM_000480.3) | Missense Mutation (SNP) | VAF 309/851 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV67331086; called by muse, mutect2, varscan2
- AMY1C | c.955G>T p.G319* | Nonsense Mutation (SNP) | VAF 232/1014 reads (23%) | catalogued as COSV100915249; called by mutect2, varscan2
- AMZ1 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 183/484 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs749021540, COSV100406368; called by muse, mutect2, varscan2
- AMZ2 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 180/546 reads (33%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.71); catalogued as rs782741991, COSV100703152; called by muse, mutect2, varscan2
- ANG | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 273/839 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs764224898; called by muse, mutect2, varscan2
- ANGEL1 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 202/489 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1176619007, COSV51871877; called by muse, mutect2, varscan2
- ANK2 | c.6874C>T p.R2292* | Nonsense Mutation (SNP) | VAF 495/1232 reads (40%) | catalogued as COSV100001468; called by muse, mutect2, varscan2
- ANK2 | c.11632C>T p.P3878S | Missense Mutation (SNP) | VAF 290/854 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs369756604; called by muse, mutect2, varscan2
- ANK3 | c.7244C>T p.P2415L | Missense Mutation (SNP) | VAF 280/838 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs372041619; called by muse, mutect2, varscan2
- ANK3 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 234/638 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs140324936, COSV55085351; called by muse, mutect2, varscan2
- ANKDD1A | c.77A>G p.N26S | Missense Mutation (SNP) | VAF 153/386 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV60352905; called by muse, mutect2, varscan2
- ANKFN1 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 297/847 reads (35%) | catalogued as rs761817258, COSV59462402; called by muse, mutect2, varscan2
- ANKFN1 | c.1950-1G>T p.X650_splice | Splice Site (SNP) | VAF 210/562 reads (37%) | catalogued as COSV100593094; called by mutect2, varscan2
- ANKFY1 | c.2576G>A p.R859Q (on ENST00000341657 / NM_001330063.2; = p.R860Q on NM_016376.5) | Missense Mutation (SNP) | VAF 274/742 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs765652697; called by muse, mutect2, varscan2
- ANKMY1 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 92/261 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777542459; called by muse, mutect2, varscan2
- ANKRD27 | c.1422G>A p.G474= | Splice Region (SNP) | VAF 65/199 reads (33%) | catalogued as COSV100042621; called by muse, mutect2, varscan2
- ANKRD46 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 538/1323 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.916); catalogued as rs766524755; called by muse, mutect2, varscan2
- ANKRD50 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 626/1729 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs775282610; called by muse, mutect2, varscan2
- ANKRD52 | c.1945C>T p.R649C | Missense Mutation (SNP) | VAF 317/734 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.401); catalogued as rs779734308; called by muse, mutect2, varscan2
- ANKRD6 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 313/930 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs747090603, COSV60229141; called by muse, mutect2, varscan2
- ANKRD62 | c.1439dup p.L481Afs*3 | Frame Shift Ins (INS) | VAF 170/590 reads (29%) | catalogued as rs774510795; called by mutect2, varscan2
- ANKRD65 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 130/308 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs779213980, COSV70987101; called by muse, mutect2, varscan2
- ANKRD9 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1171259566; called by muse, mutect2, varscan2
- ANKS1B | c.3265C>T p.R1089W (on ENST00000547776 / NM_152788.4; = p.R255W on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 307/825 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410929626, COSV59115659; called by muse, mutect2, varscan2
- ANKS1B | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 394/1021 reads (39%) | catalogued as COSV61377694; called by muse, mutect2, varscan2
- ANKS1B | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 437/1189 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100248945, COSV61343842; called by muse, mutect2, varscan2
- ANKS6 | c.1817A>G p.D606G | Missense Mutation (SNP) | VAF 164/423 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs757021075; called by muse, mutect2, varscan2
- ANO1 | c.1779C>T p.I593= | Splice Region (SNP) | VAF 147/402 reads (37%) | catalogued as rs201277195; called by muse, mutect2, varscan2
- ANO5 | c.1063C>A p.L355I | Missense Mutation (SNP) | VAF 409/1070 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs886042583, COSV61083507; called by muse, mutect2, varscan2
- ANO7 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 181/536 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1163971703; called by muse, mutect2, varscan2
- ANPEP | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 111/311 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as rs527736294; called by muse, mutect2, varscan2
- ANXA2R | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 270/668 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); catalogued as COSV59214696; called by muse, mutect2, varscan2
- ANXA7 | c.1375G>A p.A459T (on ENST00000372919 / NM_001320880.2; = p.A437T on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 219/597 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as rs146521289; called by muse, mutect2, varscan2
- AP002748.5 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 293/781 reads (38%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs200469305; called by muse, mutect2, varscan2
- AP002748.5 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 204/620 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.322); catalogued as rs148576114; called by muse, mutect2, varscan2
- AP1G1 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 280/721 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs199593090, COSV55488550; called by muse, mutect2, varscan2
- AP1G1 | c.929T>C p.I310T | Missense Mutation (SNP) | VAF 178/527 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1452180268; called by muse, mutect2, varscan2
- AP2A2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 212/536 reads (40%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.797); catalogued as rs752922457; called by muse, varscan2
- AP2A2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 285/714 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs549459789; called by muse, mutect2, varscan2
- AP2A2 | c.2762G>A p.R921H | Missense Mutation (SNP) | VAF 210/555 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs371126256; called by muse, mutect2, varscan2
- AP4B1 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 417/1127 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs763842373, COSV56725261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP5S1 | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 231/657 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs551425342; called by muse, mutect2, varscan2
- APBA1 | c.1828G>A p.V610M | Missense Mutation (SNP) | VAF 234/670 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759823383; called by muse, mutect2, varscan2
- APBB1 | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 296/791 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773975178; called by muse, mutect2, varscan2
- APCDD1L | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 197/609 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs374426833; called by muse, mutect2, varscan2
- APEH | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 234/632 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs750286026; called by muse, mutect2, varscan2
- API5 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 308/878 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs1286304647; called by muse, mutect2, varscan2
- APLP2 | c.402C>T p.L134= | Splice Region (SNP) | VAF 274/735 reads (37%) | catalogued as rs150028786; called by muse, mutect2, varscan2
- APOB | c.10415C>T p.T3472I | Missense Mutation (SNP) | VAF 377/1022 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV51921929; called by muse, mutect2, varscan2
- APOBEC3B | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 252/694 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1335435845; called by muse, mutect2, varscan2
- APOL3 | c.485A>G p.K162R (on ENST00000349314 / NM_145640.2; = p.K91R on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 380/1006 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs1172094798; called by muse, mutect2, varscan2
- APOLD1 | c.805A>C p.I269L (on ENST00000326765 / NM_001130415.2; = p.I238L on NM_030817.3) | Missense Mutation (SNP) | VAF 210/506 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs749522379; called by muse, mutect2, varscan2
- ARAP1 | c.3954+1G>A p.X1318_splice (on ENST00000393609 / NM_001040118.2; = p.X1073_splice on NM_015242.4) | Splice Site (SNP) | VAF 165/440 reads (38%) | catalogued as rs372533054; called by muse, varscan2
- ARF3 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 299/834 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.042); catalogued as rs1246000356, COSV99873021; called by muse, mutect2, varscan2
- ARFGAP3 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 268/752 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs748596047, COSV54312799; called by muse, mutect2, varscan2
- ARFGEF1 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 500/1344 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs149899042; called by muse, mutect2, varscan2
- ARHGAP18 | c.488dup p.N163Kfs*8 | Frame Shift Ins (INS) | VAF 308/888 reads (35%) | catalogued as rs749346165; called by mutect2, varscan2
- ARHGAP20 | c.1450C>A p.L484I | Missense Mutation (SNP) | VAF 270/837 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV99503255; called by muse, mutect2, varscan2
- ARHGAP21 | c.4996C>T p.R1666W | Missense Mutation (SNP) | VAF 236/834 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs375897262; called by muse, mutect2, varscan2
- ARHGAP23 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 130/316 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs1419439465; called by muse, mutect2, varscan2
- ARHGAP23 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 289/723 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.018); catalogued as rs750856610; called by muse, mutect2, varscan2
- ARHGAP24 | c.1758dup p.N587Efs*3 (on ENST00000395184 / NM_001025616.3; = p.N494Efs*3 on NM_031305.3) | Frame Shift Ins (INS) | VAF 351/1052 reads (33%) | catalogued as rs1196259804; called by mutect2, pindel, varscan2
- ARHGAP24 | c.2014C>T p.R672* (on ENST00000395184 / NM_001025616.3; = p.R579* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 190/788 reads (24%) | catalogued as rs1236556390; called by mutect2, varscan2
- ARHGAP26 | c.576G>T p.K192N | Missense Mutation (SNP) | VAF 356/965 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278151523; called by muse, mutect2, varscan2
- ARHGAP31 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 172/477 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs781008921; called by muse, mutect2, varscan2
- ARHGAP31 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 287/718 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV51798776; called by muse, mutect2, varscan2
- ARHGAP31 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 251/684 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV51793495; called by muse, mutect2, varscan2
- ARHGAP35 | c.4000C>A p.P1334T | Missense Mutation (SNP) | VAF 202/536 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.717); catalogued as COSV68329330; called by muse, mutect2, varscan2
- ARHGAP39 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 207/499 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs777655506; called by muse, mutect2, varscan2
- ARHGAP6 | c.2449C>T p.R817C (on ENST00000337414 / NM_013427.3; = p.R614C on NM_013423.3) | Missense Mutation (SNP) | VAF 229/291 reads (79%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.926); catalogued as rs750326704; called by muse, mutect2, varscan2
- ARHGDIG | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 111/261 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537147515; called by muse, mutect2, varscan2
- ARHGEF1 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 172/493 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.166); catalogued as rs139162951; called by muse, mutect2, varscan2
- ARHGEF10 | c.1498G>A p.D500N (on ENST00000398564; = p.D475N on NM_014629.4) | Missense Mutation (SNP) | VAF 261/702 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372895762; called by muse, mutect2, varscan2
- ARHGEF10L | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 223/533 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.093); catalogued as rs375888992; called by muse, mutect2, varscan2
- ARHGEF11 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 286/1173 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs142168815; called by muse, mutect2, varscan2
- ARHGEF11 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 335/617 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1014680705; called by muse, mutect2, varscan2
- ARHGEF15 | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 112/269 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866909786, COSV62724502; called by muse, mutect2, varscan2
- ARHGEF16 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 97/231 reads (42%) | catalogued as rs761184077, COSV65681674; called by muse, mutect2, varscan2
- ARHGEF18 | c.1321C>T p.R441W (on ENST00000359920 / NM_001130955.2; = p.R337W on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/435 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367800762; called by muse, mutect2, varscan2
- ARHGEF18 | c.2330C>T p.A777V (on ENST00000359920 / NM_001130955.2; = p.A673V on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/271 reads (39%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs1257671231; called by muse, mutect2, varscan2
- ARHGEF18 | c.2479C>T p.R827C (on ENST00000359920 / NM_001130955.2; = p.R723C on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1442552996; called by muse, varscan2
- ARHGEF40 | c.2948G>A p.R983H | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs375463249; called by muse, mutect2, varscan2
- ARL16 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 255/634 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs762722358; called by muse, mutect2, varscan2
- ARL4A | c.184A>C p.T62P | Missense Mutation (SNP) | VAF 493/1287 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV63319734; called by muse, mutect2, varscan2
- ARMC4 | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 320/965 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV53466519; called by muse, mutect2, varscan2
- ARMC5 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 106/299 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as rs1431164175; called by muse, mutect2, varscan2
- ARMC5 | c.2245G>A p.D749N | Missense Mutation (SNP) | VAF 151/380 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs759471751; called by muse, mutect2, varscan2
- ARMC9 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 230/589 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs570719658; called by muse, mutect2, varscan2
- ARMCX2 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 330/421 reads (78%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.084); catalogued as rs782669292, COSV100168159; called by muse, mutect2, varscan2
- ARMCX2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 323/624 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs781812794, COSV57529190; called by muse, mutect2, varscan2
- ARNTL | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 197/485 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV62987704; called by muse, mutect2, varscan2
- ARR3 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 299/372 reads (80%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs371232872; called by muse, mutect2, varscan2
- ARRB1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 201/524 reads (38%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.745); catalogued as rs1382704856; called by muse, varscan2
- ARSF | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 345/424 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs772851609; called by muse, mutect2, varscan2
- ARSH | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 290/397 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.337); catalogued as COSV66963109; called by muse, mutect2, varscan2
- ARVCF | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 191/514 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369029314; called by muse, mutect2, varscan2
- ASAP1 | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 254/713 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.99); catalogued as COSV63050035; called by muse, mutect2, varscan2
- ASAP3 | c.2519C>T p.S840L | Missense Mutation (SNP) | VAF 256/672 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1260013457, COSV60873426; called by muse, mutect2, varscan2
- ASB1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 193/571 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs751409065, COSV52827130; called by muse, mutect2, varscan2
- ASB11 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 436/567 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs755412962, COSV60354537; called by muse, mutect2, varscan2
- ASB4 | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 355/892 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.75); catalogued as rs762395018, COSV57507880; called by muse, mutect2, varscan2
- ASB7 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 285/669 reads (43%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.948); catalogued as rs1356267474; called by muse, mutect2, varscan2
- ASCC3 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 555/1553 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV61233783; called by muse, mutect2, varscan2
- ASCL3 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 273/637 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751505172; called by muse, mutect2, varscan2
- ASL | c.1250+4C>T | Splice Region (SNP) | VAF 109/317 reads (34%) | catalogued as rs374333124; called by muse, mutect2, varscan2
- ASPG | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs771282088, COSV71933643; called by muse, mutect2, varscan2
- ASPHD1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs1373928503, COSV100435332; called by muse, varscan2
- ASPM | c.9107T>C p.I3036T | Missense Mutation (SNP) | VAF 588/2215 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776674394; called by muse, mutect2, varscan2
- ASPSCR1 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 255/691 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs776182994, COSV60727639; called by muse, mutect2, varscan2
- ASXL1 | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 270/831 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs1456774256; called by muse, mutect2, varscan2
- ASXL2 | c.2293C>T p.P765S | Missense Mutation (SNP) | VAF 192/505 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.03); catalogued as COSV55460298; called by muse, mutect2, varscan2
- ATAD3A | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 257/690 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs145811436; called by muse, mutect2, varscan2
- ATAD3C | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 291/786 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); catalogued as rs554378836; called by muse, varscan2
- ATAD5 | c.4908A>C p.K1636N | Missense Mutation (SNP) | VAF 521/1216 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as rs770672661; called by mutect2, varscan2
- ATCAY | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 268/696 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1372801681; called by muse, mutect2, varscan2
- ATCAY | c.903C>A p.S301R | Missense Mutation (SNP) | VAF 109/346 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM032846; called by muse, mutect2, varscan2
- ATG101 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 169/398 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as rs751591793, COSV100401058; called by muse, mutect2, varscan2
- ATG2B | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 247/679 reads (36%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as rs200455327; called by muse, mutect2, varscan2
- ATG9B | c.2756G>A p.R919Q | Missense Mutation (SNP) | VAF 177/469 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs950890773, COSV99872244; called by muse, mutect2, varscan2
- ATM | c.8177C>A p.A2726D | Missense Mutation (SNP) | VAF 479/1330 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM990220; called by muse, mutect2, varscan2
- ATP10A | c.3502C>T p.P1168S | Missense Mutation (SNP) | VAF 258/710 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.118); catalogued as rs748117534; called by muse, varscan2
- ATP10A | c.2635C>T p.R879C | Missense Mutation (SNP) | VAF 270/742 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as rs763611613, COSV63512846, COSV63515586; called by muse, mutect2, varscan2
- ATP10A | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 122/368 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755196001, COSV63516408; called by muse, varscan2
- ATP10A | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 184/473 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs1567379263, COSV63516972; called by muse, varscan2
- ATP10D | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 560/1466 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as rs770945581, COSV56703258; called by muse, mutect2, varscan2
- ATP10D | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 330/899 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200004371; called by muse, mutect2, varscan2
- ATP11A | c.1016G>T p.R339M | Missense Mutation (SNP) | VAF 146/524 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.704); catalogued as COSV52108673; called by muse, mutect2
- ATP11A | c.2459C>T p.T820M | Missense Mutation (SNP) | VAF 235/621 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760167980; called by muse, mutect2, varscan2
- ATP1A3 | c.3038G>A p.R1013H (on ENST00000545399 / NM_001256214.2; = p.R1000H on NM_152296.5) | Missense Mutation (SNP) | VAF 177/499 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV57484978; called by muse, mutect2, varscan2
- ATP1A3 | c.800G>A p.R267H (on ENST00000545399 / NM_001256214.2; = p.R254H on NM_152296.5) | Missense Mutation (SNP) | VAF 165/435 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs1315342682, COSV100132466; called by muse, mutect2, varscan2
- ATP1A4 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 280/1104 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as rs769485753, COSV100927581, COSV63629152; called by muse, varscan2
- ATP2A1 | c.2707G>A p.V903M | Missense Mutation (SNP) | VAF 124/366 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746102754; called by muse, mutect2, varscan2
- ATP2A2 | c.3118T>G p.F1040V | Missense Mutation (SNP) | VAF 168/485 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as rs985767557, COSV57875988; called by muse, mutect2, varscan2
- ATP2B2 | c.1783C>T p.R595C (on ENST00000352432; = p.R561C on NM_001683.5) | Missense Mutation (SNP) | VAF 160/373 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776463160, COSV59494867; called by muse, mutect2, varscan2
- ATP2C2 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 210/533 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as rs1272442871; called by muse, mutect2, varscan2
- ATP4A | c.1777G>A p.G593S | Missense Mutation (SNP) | VAF 185/565 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.152); catalogued as rs1427434013, COSV52870316; called by muse, mutect2, varscan2
- ATP6AP2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 336/464 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs751433380; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V0D1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 132/340 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs777256753, COSV52097335; called by muse, mutect2, varscan2
- ATP6V1C1 | c.506T>G p.I169S | Missense Mutation (SNP) | VAF 439/1075 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV67778560; called by muse, mutect2, varscan2
- ATP6V1FNB | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 295/872 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.565); catalogued as rs1484522571; called by muse, mutect2, varscan2
- ATP6V1H | c.995G>A p.S332N | Missense Mutation (SNP) | VAF 457/1264 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV62218833; called by muse, mutect2, varscan2
- ATP6V1H | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 42/1241 reads (3%) | catalogued as COSV62217366; called by muse, mutect2
- ATP7A | c.368G>T p.R123I | Missense Mutation (SNP) | VAF 438/543 reads (81%) | SIFT deleterious (0.05); PolyPhen benign (0.361); catalogued as COSV58447181; called by muse, mutect2, varscan2
- ATP8B4 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 467/1266 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs780870766; called by muse, mutect2, varscan2
- ATPAF2 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 154/426 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs577409637, COSV58261744; called by muse, mutect2, varscan2
- ATXN2 | c.922G>A p.A308T (on ENST00000550104; = p.A148T on NM_002973.4) | Missense Mutation (SNP) | VAF 308/822 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs931962514; called by muse, mutect2, varscan2
- ATXN7 | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 414/1083 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs1369874836, COSV55756867; called by muse, mutect2, varscan2
- ATXN7L3 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 304/794 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.141); catalogued as rs756514522; called by muse, mutect2, varscan2
- AURKC | c.749G>A p.R250H (on ENST00000302804 / NM_001015878.2; = p.R216H on NM_003160.3) | Missense Mutation (SNP) | VAF 190/551 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs534798496, COSV100248977; called by muse, varscan2
- AUTS2 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 140/419 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs1277387034, COSV61424313; called by muse, mutect2, varscan2
- AUTS2 | c.2539G>A p.V847I | Missense Mutation (SNP) | VAF 172/506 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs751246676, COSV100719828; called by muse, mutect2, varscan2
- AVIL | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 178/628 reads (28%) | catalogued as rs1372022726; called by muse, mutect2, varscan2
- AXL | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 212/583 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.077); catalogued as rs545028002, COSV56568356; called by muse, varscan2
- AZGP1 | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 119/461 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104392429; called by muse, mutect2, varscan2
- B4GALNT4 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 162/396 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs757420384; called by muse, mutect2, varscan2
- B4GALT2 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 292/703 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs140519554; called by muse, mutect2, varscan2
- BACE2 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 369/965 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.572); catalogued as rs749800434, COSV57739787, COSV57742038; called by muse, mutect2, varscan2
- BAHCC1 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 113/325 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as rs1555645761; called by muse, mutect2, varscan2
- BAHCC1 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 148/352 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs376664843; called by muse, mutect2, varscan2
- BAHCC1 | c.2938G>A p.A980T | Missense Mutation (SNP) | VAF 126/358 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs782637162; called by muse, mutect2, varscan2
- BAHCC1 | c.4541C>T p.A1514V | Missense Mutation (SNP) | VAF 145/316 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as rs1294495291, COSV57026991; called by muse, mutect2, varscan2
- BANF1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 193/516 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.051); catalogued as COSV56463394; called by muse, mutect2, varscan2
- BANP | c.1192G>A p.A398T (on ENST00000286122; = p.A370T on NM_017869.4) | Missense Mutation (SNP) | VAF 196/552 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.988); catalogued as rs774641733, COSV53741275; called by muse, varscan2
- BASP1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 248/555 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs746697251, COSV59472069; called by muse, mutect2, varscan2
- BASP1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 179/448 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as rs1217149957; called by muse, mutect2, varscan2
- BBX | c.2702C>T p.A901V (on ENST00000325805 / NM_001142568.3; = p.A871V on NM_020235.7) | Missense Mutation (SNP) | VAF 540/1412 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1297578261; called by mutect2, varscan2
- BCAR1 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 127/286 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1439673307; called by muse, mutect2, varscan2
- BCAS3 | c.1889G>A p.R630Q (on ENST00000390652 / NM_001353144.2; = p.R615Q on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 414/1112 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as rs756844690; called by muse, mutect2, varscan2
- BCL2L11 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 98/355 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV58031267; called by muse, mutect2, varscan2
- BCL3 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 106/332 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.757); catalogued as COSV99378275; called by muse, mutect2, varscan2
- BCL7B | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 129/356 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); catalogued as rs1554584899; called by muse, mutect2, varscan2
- BCOR | c.3982C>T p.Q1328* (on ENST00000378444 / NM_001123385.2; = p.Q1294* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 431/534 reads (81%) | catalogued as COSV100654437; called by muse, mutect2, varscan2
- BCORL1 | c.4258C>T p.R1420* | Nonsense Mutation (SNP) | VAF 466/617 reads (76%) | catalogued as COSV54393900; called by muse, mutect2, varscan2
- BDKRB2 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 153/495 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.233); catalogued as rs146650268; called by muse, mutect2, varscan2
- BDP1 | c.4310G>A p.R1437Q | Missense Mutation (SNP) | VAF 632/1754 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs201608641; called by muse, mutect2, varscan2
- BEND3 | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 271/696 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1252497291; called by muse, mutect2, varscan2
- BEND3 | c.83C>A p.A28D | Missense Mutation (SNP) | VAF 370/892 reads (41%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.025); catalogued as rs1279396934; called by muse, mutect2, varscan2
- BEST4 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 313/829 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs140513742; called by muse, mutect2, varscan2
- BFAR | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 277/733 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.675); catalogued as rs372892824; called by muse, mutect2, varscan2
- BFAR | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 184/514 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1045706654; called by muse, mutect2, varscan2
- BFSP2 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 149/475 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs200874347, COSV56588428; called by muse, mutect2, varscan2
- BHLHA15 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 151/455 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs769516401; called by muse, mutect2, varscan2
- BICD2 | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 155/400 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs767576124; called by muse, mutect2, varscan2
- BICDL2 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 113/309 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs774955463; called by muse, mutect2, varscan2
- BICRA | c.1178C>A p.A393D | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV67603566; called by muse, mutect2, varscan2
- BICRAL | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 124/365 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs771711586; called by muse, mutect2, varscan2
- BIRC2 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 436/1347 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745428800; called by muse, mutect2, varscan2
- BLOC1S2 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 431/1007 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV100705039; called by muse, mutect2, varscan2
- BMI1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 455/1290 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as rs1469458151; called by muse, mutect2, varscan2
- BMP1 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 159/420 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs370064009; called by muse, mutect2, varscan2
- BMP10 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 409/1018 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV99770530; called by muse, mutect2, varscan2
- BMP2K | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 318/928 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as rs1352109762; called by muse, varscan2
- BMP2K | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 461/1217 reads (38%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs769519712, COSV55010787; called by muse, mutect2, varscan2
- BMP2K | c.3102A>C p.E1034D | Missense Mutation (SNP) | VAF 333/859 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1292141769; called by muse, mutect2, varscan2
- BMP3 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 411/1190 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs140653938; called by muse, mutect2, varscan2
- BMP3 | c.938A>G p.E313G | Missense Mutation (SNP) | VAF 306/898 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV51096637; called by muse, mutect2, varscan2
- BMPR2 | c.2677C>T p.R893W | Missense Mutation (SNP) | VAF 317/818 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs764248124; called by muse, mutect2, varscan2
- BNIPL | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 181/737 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs751951536; called by muse, mutect2, varscan2
- BOC | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 436/1051 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.671); catalogued as rs746007747, COSV56351560; called by muse, mutect2, varscan2
- BOC | c.2596G>A p.V866I | Missense Mutation (SNP) | VAF 302/827 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs550532112; called by muse, mutect2, varscan2
- BOD1L1 | c.5258G>A p.R1753H | Missense Mutation (SNP) | VAF 284/803 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs112328769, COSV99238510; called by muse, mutect2, varscan2
- BOD1L2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 276/733 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1481967553, COSV101649313; called by muse, mutect2, varscan2
- BPI | c.937G>T p.D313Y (on ENST00000262865; = p.D309Y on NM_001725.3) | Missense Mutation (SNP) | VAF 273/655 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99480914; called by muse, mutect2, varscan2
- BPTF | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 451/1211 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1460282103; called by muse, mutect2, varscan2
- BRAP | c.359A>C p.K120T | Missense Mutation (SNP) | VAF 380/995 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV58159856, COSV58162102; called by mutect2, varscan2
- BRCA2 | c.2838T>G p.D946E | Missense Mutation (SNP) | VAF 668/1862 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.105); catalogued as rs149753706; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.5039C>A p.S1680Y | Missense Mutation (SNP) | VAF 583/1596 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1555284041, COSV66455828; ClinVar: uncertain significance; called by muse, varscan2
- BRCA2 | c.6398C>T p.S2133L | Missense Mutation (SNP) | VAF 374/1071 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV66452792; called by muse, mutect2, varscan2
- BRCA2 | c.6679G>A p.A2227T | Missense Mutation (SNP) | VAF 588/1588 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs431825345; ClinVar: uncertain significance; called by muse, varscan2
- BRCC3 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 345/460 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV57461717, COSV57461891; called by muse, mutect2, varscan2
- BRD2 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 367/996 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as rs752255187; called by muse, mutect2, varscan2
- BRD2 | c.2243A>C p.N748T | Missense Mutation (SNP) | VAF 294/824 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV66372490; called by muse, mutect2, varscan2
- BRD3 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 260/689 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs768238584; called by muse, mutect2, varscan2
- BRD4 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 183/485 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1324868843; called by muse, mutect2, varscan2
- BRD7 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 300/858 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs892698215, COSV67158498; called by muse, varscan2
- BRINP3 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 337/1359 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as rs745308648, COSV100818636, COSV66522732; called by muse, mutect2, varscan2
- BRIP1 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 520/1349 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289648562; ClinVar: uncertain significance; called by muse, varscan2
- BRPF1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 249/700 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1465578133, COSV57403643; called by muse, mutect2, varscan2
- BRPF1 | c.2723C>T p.P908L | Missense Mutation (SNP) | VAF 184/484 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); catalogued as rs541388566, COSV57402934; called by muse, mutect2, varscan2
- BRPF1 | c.3362C>A p.P1121H | Missense Mutation (SNP) | VAF 312/835 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57351632; called by muse, mutect2, varscan2
- BRPF3 | c.742T>A p.Y248N | Missense Mutation (SNP) | VAF 292/685 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60208907; called by muse, mutect2, varscan2
- BRWD3 | c.3977G>A p.R1326Q | Missense Mutation (SNP) | VAF 501/633 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747841394; called by muse, mutect2, varscan2
- BSN | c.3359G>A p.R1120H | Missense Mutation (SNP) | VAF 107/322 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771863939; called by muse, mutect2, varscan2
- BTBD2 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 117/266 reads (44%) | catalogued as COSV55308735; called by muse, mutect2, varscan2
- BTBD7 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 241/680 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV58285798; called by muse, mutect2, varscan2
- BTBD8 | c.5042A>G p.H1681R (on ENST00000636805 / NM_001376131.1; = p.H1168R on NM_015237.4) | Missense Mutation (SNP) | VAF 542/1564 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.052); catalogued as rs932905130; called by muse, mutect2, varscan2
- BTLA | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 174/470 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs754296727; called by muse, mutect2, varscan2
- BTNL3 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 355/965 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as rs763949226; called by muse, mutect2, varscan2
- BZW2 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 170/558 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); catalogued as COSV51754646; called by muse, mutect2, varscan2
- C10orf67 | c.590C>T p.A197V (on ENST00000636213 / NM_001365862.2; = p.A165V on NM_001351306.2) | Missense Mutation (SNP) | VAF 160/626 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.133); catalogued as rs1022593371; called by muse, mutect2, varscan2
- C11orf45 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 178/486 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs545751134, COSV57963725; called by muse, varscan2
- C12orf45 | c.452G>A p.S151N | Missense Mutation (SNP) | VAF 428/1228 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs745896625; called by muse, mutect2, varscan2
- C15orf39 | c.2582C>A p.S861Y | Missense Mutation (SNP) | VAF 138/296 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100641450; called by muse, mutect2, varscan2
- C16orf90 | c.115G>A p.A39T (on ENST00000399645 / NM_001353385.2; = p.A30T on NM_001080524.2) | Missense Mutation (SNP) | VAF 112/327 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs777586445, COSV68714593; called by muse, mutect2, varscan2
- C16orf96 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 228/616 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.144); catalogued as rs1229000473; called by muse, mutect2, varscan2
- C19orf54 | c.392+2T>G p.X131_splice | Splice Site (SNP) | VAF 136/314 reads (43%) | catalogued as rs1305314300; called by muse, varscan2
- C1QL4 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 191/569 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1179163476; called by muse, mutect2, varscan2
- C1orf94 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 252/722 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as rs1425644805; called by muse, mutect2, varscan2
- C20orf144 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 214/605 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs955531744, COSV55775540, COSV99042752; called by muse, mutect2, varscan2
- C2orf81 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 180/521 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV51763890; called by muse, mutect2, varscan2
- C4A | c.3164G>A p.R1055Q | Missense Mutation (SNP) | VAF 187/568 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs143990092; called by muse, mutect2, varscan2
- C4orf54 | c.3964C>T p.R1322W | Missense Mutation (SNP) | VAF 186/422 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1355948896; called by muse, mutect2, varscan2
- C4orf54 | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 255/640 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); catalogued as COSV72766953; called by muse, mutect2, varscan2
- C5orf34 | c.1249C>A p.L417I | Missense Mutation (SNP) | VAF 364/908 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561208129, COSV60930082; called by muse, mutect2, varscan2
- C6 | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 424/1210 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54704266; called by muse, mutect2, varscan2
- C6orf118 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 306/773 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs1054831688, COSV57816003; called by muse, mutect2, varscan2
- C8orf48 | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 364/1058 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs1269697569; called by muse, mutect2, varscan2
- C8orf58 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 205/574 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.32); catalogued as rs771271445; called by muse, mutect2, varscan2
- C9orf153 | c.47C>A p.A16D | Missense Mutation (SNP) | VAF 331/953 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs924986615, COSV59252191; called by muse, mutect2, varscan2
- CA1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 262/849 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as COSV56277266, COSV99810133; called by muse, mutect2, varscan2
- CACNA1B | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 341/869 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs199937787; called by muse, varscan2
- CACNA1B | c.1083G>T p.K361N | Missense Mutation (SNP) | VAF 247/637 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53136426; called by muse, mutect2, varscan2
- CACNA1B | c.2008T>C p.Y670H | Missense Mutation (SNP) | VAF 226/633 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99495724; called by muse, mutect2, varscan2
- CACNA1C | c.5941C>T p.R1981* (on ENST00000399634 / NM_001167625.1; = p.R1910* on NM_000719.7) | Nonsense Mutation (SNP) | VAF 257/643 reads (40%) | catalogued as rs1556291640, COSV59741294, COSV59776352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 275/989 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs999139568; called by muse, mutect2, varscan2
- CACNA1E | c.6529C>T p.R2177* (on ENST00000367573 / NM_001205293.3; = p.R2134* on NM_000721.4) | Nonsense Mutation (SNP) | VAF 482/828 reads (58%) | catalogued as rs1325877084, COSV100704923; called by muse, mutect2, varscan2
- CACNA1H | c.3502T>C p.S1168P | Missense Mutation (SNP) | VAF 106/278 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs1009747901; called by muse, mutect2, varscan2
- CACNA1I | c.3589G>A p.G1197S | Missense Mutation (SNP) | VAF 171/510 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.204); catalogued as rs1277984291; called by muse, mutect2, varscan2
- CACNA1S | c.3440A>G p.N1147S | Missense Mutation (SNP) | VAF 267/1024 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs762768883; called by muse, mutect2, varscan2
- CACNA1S | c.1907T>G p.L636R | Missense Mutation (SNP) | VAF 506/926 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV62942813; called by muse, mutect2, varscan2
- CACNA2D3 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 400/1094 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs775275975, COSV55510818; called by muse, mutect2, varscan2
- CACNA2D4 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 213/531 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376351407; called by muse, mutect2, varscan2
- CACNA2D4 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 311/768 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1173208667, COSV54962310; called by muse, mutect2, varscan2
- CACTIN | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1159732817; called by muse, mutect2
- CAD | c.4241G>A p.R1414H | Missense Mutation (SNP) | VAF 360/936 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV53033680; called by muse, mutect2, varscan2
- CADM1 | c.994+5G>A | Splice Region (SNP) | VAF 275/751 reads (37%) | catalogued as rs997641669, COSV59023915; called by muse, mutect2, varscan2
- CADPS | c.2876G>A p.R959H | Missense Mutation (SNP) | VAF 265/776 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs376315928; called by muse, mutect2, varscan2
- CALHM5 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 490/1290 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.847); catalogued as rs571775020, COSV62068805; called by muse, mutect2, varscan2
- CAMK2G | c.1501G>A p.V501M (on ENST00000423381 / NM_001367518.1; = p.V438M on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 190/630 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.656); catalogued as rs1243870956, COSV55214280; called by muse, mutect2, varscan2
- CAMSAP1 | c.2720G>A p.R907H | Missense Mutation (SNP) | VAF 95/264 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747762999, COSV56727440; called by muse, mutect2, varscan2
- CAMSAP2 | c.3431A>G p.Y1144C (on ENST00000236925 / NM_001297707.2; = p.Y1133C on NM_203459.3) | Missense Mutation (SNP) | VAF 443/1776 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.264); catalogued as rs765232156; called by muse, mutect2, varscan2
- CAND2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 317/865 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs370436475; called by muse, mutect2, varscan2
- CAPN1 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 310/832 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs369163523; called by muse, mutect2, varscan2
- CAPN1 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 230/622 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54200118; called by muse, mutect2, varscan2
- CAPN12 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 139/388 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs759140142; called by muse, mutect2, varscan2
- CAPN13 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 285/793 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs762769811; called by muse, mutect2, varscan2
- CAPN6 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 452/571 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs749806826; called by muse, mutect2, varscan2
- CAPN9 | c.1991T>C p.V664A | Missense Mutation (SNP) | VAF 353/693 reads (51%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as rs746787858, COSV55230511; called by muse, mutect2, varscan2
- CAPZA2 | c.658-1G>A p.X220_splice | Splice Site (SNP) | VAF 202/598 reads (34%) | catalogued as COSV100754003; called by muse, mutect2, varscan2
- CAPZA3 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 349/952 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.038); catalogued as rs1282452558; called by muse, mutect2, varscan2
- CAPZB | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 172/458 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.415); catalogued as COSV51647348; called by mutect2, varscan2
- CARD10 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 319/784 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as rs758216874; called by muse, mutect2, varscan2
- CARD11 | c.3437C>T p.T1146I | Missense Mutation (SNP) | VAF 261/658 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs771514857; called by muse, mutect2, varscan2
- CARD17 | c.93G>T p.E31D | Missense Mutation (SNP) | VAF 286/760 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.648); catalogued as rs1205673708; called by muse, mutect2, varscan2
- CARD8 | c.1217A>G p.Y406C (on ENST00000651546 / NM_001184900.3; = p.Y356C on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 294/696 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs369625179; called by muse, mutect2, varscan2
- CARS1 | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 235/628 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1461372759, COSV53453285; called by muse, mutect2, varscan2
- CASC3 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 122/345 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1315065108; called by muse, mutect2, varscan2
- CASP10 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 361/956 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs140813639; called by muse, mutect2, varscan2
- CASP5 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 267/756 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.094); catalogued as rs547070785; called by muse, mutect2, varscan2
- CASP5 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 209/614 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs201179331, COSV52830238; called by muse, mutect2, varscan2
- CASP8AP2 | c.4543C>T p.R1515* | Nonsense Mutation (SNP) | VAF 264/826 reads (32%) | catalogued as COSV99386954; called by muse, mutect2, varscan2
- CASQ1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 139/528 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs773804780, COSV63624361; called by muse, mutect2, varscan2
- CAST | c.75dup p.H26Tfs*11 (on ENST00000341926; = p.H109Tfs*11 on NM_001750.7 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 259/783 reads (33%) | catalogued as rs1324899428; called by mutect2, pindel, varscan2
- CASZ1 | c.4555C>T p.R1519C | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1290829063; called by muse, mutect2, varscan2
- CATSPERD | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 93/238 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58464429, COSV58465204; called by muse, mutect2, varscan2
- CATSPERE | c.1640C>A p.S547Y | Missense Mutation (SNP) | VAF 824/1490 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.729); catalogued as COSV63681701; called by muse, mutect2, varscan2
- CAVIN1 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 79/201 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs769110133, COSV63811465; called by muse, mutect2, varscan2
- CBFA2T3 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 36/474 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV51930171, COSV99046927; called by muse, mutect2
- CBLL2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 426/549 reads (78%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs373087492, COSV100081481; called by muse, mutect2, varscan2
- CBLN4 | c.347G>T p.R116I | Missense Mutation (SNP) | VAF 324/897 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.771); catalogued as COSV50354316, COSV99290416; called by muse, mutect2, varscan2
- CBR1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 152/378 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs867128163, COSV51739533; called by muse, mutect2, varscan2
- CBWD1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 130/1538 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1563789758; called by muse, mutect2
- CC2D1B | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 175/503 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750480906, COSV104370848; called by muse, mutect2, varscan2
- CCAR2 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 300/801 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.799); catalogued as COSV52386508; called by muse, mutect2, varscan2
- CCBE1 | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 195/513 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV71672925; called by muse, mutect2, varscan2
- CCDC102A | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 201/541 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs779789420; called by muse, varscan2
- CCDC102A | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 193/507 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs774746642; called by muse, mutect2, varscan2
- CCDC130 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 126/278 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55582961; called by muse, varscan2
- CCDC130 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 290/771 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs752468307, COSV55584499; called by muse, mutect2, varscan2
- CCDC130 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 138/404 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769878374; called by muse, mutect2, varscan2
- CCDC151 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 143/423 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1431454771, COSV62698001; called by muse, mutect2, varscan2
- CCDC157 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 248/735 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs763703415, COSV99306685; called by muse, mutect2, varscan2
- CCDC158 | c.3029G>A p.R1010H | Missense Mutation (SNP) | VAF 446/1218 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs375412402; called by muse, mutect2, varscan2
- CCDC159 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 122/354 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs775535549; called by muse, mutect2, varscan2
- CCDC166 | c.473T>G p.I158S | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV72638856; called by muse, mutect2
- CCDC168 | c.11491C>T p.R3831W | Missense Mutation (SNP) | VAF 465/1253 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs756756338, COSV59419606; called by muse, mutect2, varscan2
- CCDC170 | c.876G>T p.K292N | Missense Mutation (SNP) | VAF 396/1073 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV53336650; called by muse, mutect2, varscan2
- CCDC177 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 139/387 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1013118839; called by muse, mutect2, varscan2
- CCDC18 | c.1892T>C p.L631S (on ENST00000343253 / NM_001306076.1; = p.L632S on NM_206886.4) | Missense Mutation (SNP) | VAF 428/1186 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.083); catalogued as rs868647726; called by muse, mutect2, varscan2
- CCDC180 | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 389/1061 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748325649; called by muse, mutect2, varscan2
- CCDC191 | c.1024A>G p.I342V | Missense Mutation (SNP) | VAF 360/970 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.421); catalogued as rs146010906; called by muse, mutect2, varscan2
- CCDC3 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 148/397 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs371834557; called by muse, mutect2, varscan2
- CCDC57 | c.1594C>T p.R532* | Nonsense Mutation (SNP) | VAF 244/724 reads (34%) | catalogued as rs776119468; called by muse, mutect2, varscan2
- CCDC66 | c.792dup p.A265Sfs*9 (on ENST00000394672 / NM_001353147.1; = p.A231Sfs*9 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 309/830 reads (37%) | catalogued as rs770432647; called by mutect2, varscan2
- CCDC74A | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 134/812 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.021); catalogued as rs769081576, COSV54608642, COSV99723938; called by muse, varscan2
- CCDC74B | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 127/503 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0.404); catalogued as rs777058872; called by muse, mutect2
- CCDC78 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 172/489 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as rs371030168; ClinVar: uncertain significance; called by muse, mutect2
- CCDC8 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 136/320 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs752157966, COSV56772396; called by muse, mutect2, varscan2
- CCDC83 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 532/1427 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs773340808; called by muse, mutect2, varscan2
- CCDC88A | c.2708C>T p.T903M | Missense Mutation (SNP) | VAF 346/1044 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370779418; called by muse, mutect2, varscan2
- CCDC88B | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 171/455 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199674677, COSV100105631; called by muse, mutect2, varscan2
- CCDC88B | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 117/366 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); catalogued as rs200112857; called by muse, mutect2, varscan2
- CCDC91 | c.817dup p.I273Nfs*28 | Frame Shift Ins (INS) | VAF 355/1238 reads (29%) | catalogued as rs751463445; called by pindel, varscan2
- CCDC97 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 109/296 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.041); catalogued as rs1286685402, COSV54189870; called by muse, mutect2, varscan2
- CCDC9B | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 120/403 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372833743, COSV66875169; called by muse, mutect2, varscan2
- CCKAR | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 120/388 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.243); catalogued as COSV55161165; called by muse, mutect2, varscan2
- CCL3L3 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 287/826 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1249997768; called by muse, mutect2, varscan2
- CCM2 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 277/764 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as rs773951494; called by muse, mutect2, varscan2
- CCND2 | c.195+2T>C p.X65_splice | Splice Site (SNP) | VAF 127/366 reads (35%) | catalogued as COSV54222475; called by muse, mutect2, varscan2
- CCNL1 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 552/1453 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1333458794, COSV55818511; called by muse, mutect2, varscan2
- CCP110 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 475/1143 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs758917792, COSV66817675; called by muse, mutect2, varscan2
- CCR7 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 215/635 reads (34%) | catalogued as rs1463167209, COSV55851192; called by muse, mutect2, varscan2
- CCSER1 | c.2464C>T p.R822W | Missense Mutation (SNP) | VAF 474/1358 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs1327494584, COSV61411301; called by muse, mutect2, varscan2
- CCT8 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 438/1194 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as rs892474753, COSV54502811; called by muse, mutect2, varscan2
- CD19 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 299/736 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); catalogued as rs1235287950, COSV61188819; called by muse, mutect2, varscan2
- CD1A | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 598/1048 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs146048507, COSV56860359; called by muse, mutect2, varscan2
- CD1D | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 571/1012 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.307); catalogued as COSV63810318; called by muse, mutect2, varscan2
- CD209 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 299/747 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs373950030; called by muse, mutect2, varscan2
- CD244 | c.1063C>T p.P355S (on ENST00000368033 / NM_001166663.2; = p.P350S on NM_016382.4) | Missense Mutation (SNP) | VAF 735/1409 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as rs544971422; called by muse, mutect2, varscan2
- CD276 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 121/334 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs747735855; called by muse, mutect2, varscan2
- CD300C | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 263/697 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as rs375373142; called by muse, varscan2
- CD300LB | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 230/544 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as rs199976982, COSV58725175, COSV58725989; called by muse, mutect2, varscan2
- CD46 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 476/937 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs200133631, COSV59734311; called by muse, mutect2, varscan2
- CD86 | c.676C>T p.R226W (on ENST00000330540 / NM_175862.5; = p.R220W on NM_006889.4) | Missense Mutation (SNP) | VAF 311/767 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs188841651, COSV52605374; called by muse, mutect2, varscan2
- CD93 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 167/493 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as rs1415230155; called by muse, mutect2, varscan2
- CDAN1 | c.2596G>A p.V866I | Missense Mutation (SNP) | VAF 264/703 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs375271914; called by muse, mutect2, varscan2
- CDC14A | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 281/801 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs371468460, COSV100325925; called by muse, mutect2, varscan2
- CDC25A | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 238/629 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100207440, COSV56770914; called by muse, mutect2, varscan2
- CDC42BPG | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 256/690 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs199579250; called by muse, mutect2, varscan2
- CDC45 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 107/285 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757736626, COSV54243984; called by muse, mutect2, varscan2
- CDC7 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 406/1120 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs770345842; called by muse, mutect2, varscan2
- CDCA3 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 284/778 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs200589400, COSV57529675; called by muse, varscan2
- CDCA8 | c.-15-7C>T | Splice Region (SNP) | VAF 105/261 reads (40%) | catalogued as rs949512137; called by muse, mutect2, varscan2
- CDH19 | c.1964A>C p.D655A | Missense Mutation (SNP) | VAF 499/1302 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV100051565; called by muse, mutect2, varscan2
- CDH2 | c.2284C>T p.P762S | Missense Mutation (SNP) | VAF 364/976 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753519915, COSV52297286; called by muse, mutect2, varscan2
- CDH20 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 237/730 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs1166288202; called by muse, mutect2, varscan2
- CDH22 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 146/401 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as rs376156631; called by muse, mutect2, varscan2
- CDH22 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 249/664 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs1004210893, COSV64839960; called by muse, mutect2, varscan2
- CDH23 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 186/450 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as rs750201320; called by muse, mutect2, varscan2
- CDH24 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 131/362 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774976362; called by muse, mutect2, varscan2
- CDH26 | c.2332G>A p.G778S (on ENST00000348616 / NM_177980.4; = p.G111S on NM_021810.6) | Missense Mutation (SNP) | VAF 294/746 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.018); catalogued as rs200967688; called by muse, mutect2, varscan2
- CDH5 | c.1657C>A p.L553I | Missense Mutation (SNP) | VAF 214/557 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58518192; called by muse, mutect2, varscan2
- CDH9 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 377/1003 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs763497540, COSV50254621, COSV50464003; called by muse, mutect2, varscan2
- CDHR1 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 193/524 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373314306; called by muse, mutect2, varscan2
- CDK10 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 254/682 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs748526308, COSV58416140; called by muse, mutect2, varscan2
- CDK8 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 303/782 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs529227329; called by muse, mutect2, varscan2
- CDKL5 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 460/606 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as rs587783156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDON | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 449/1044 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs551721918, COSV54996503; called by muse, mutect2, varscan2
- CDR2L | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 184/498 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV61501692; called by muse, varscan2
- CDX1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 87/286 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV51568430; called by muse, mutect2, varscan2
- CEACAM6 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 162/416 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV52268266; called by muse, mutect2, varscan2
- CEBPZ | c.3111T>G p.H1037Q | Missense Mutation (SNP) | VAF 342/898 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1048564848; called by muse, varscan2
- CEBPZ | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 358/990 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52207511; called by muse, varscan2
- CEBPZOS | c.32A>C p.K11T | Missense Mutation (SNP) | VAF 448/1032 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as rs998519113; called by muse, varscan2
- CELF3 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 286/951 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs966059814, COSV51881765; called by muse, mutect2, varscan2
- CELSR2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 274/751 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54779467; called by muse, mutect2, varscan2
- CELSR2 | c.7745C>A p.S2582Y | Missense Mutation (SNP) | VAF 250/668 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99072298; called by muse, mutect2, varscan2
- CEMIP | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 155/397 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs768948748; called by muse, mutect2, varscan2
- CENPBD1 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 44/1243 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51920490; called by muse, mutect2
- CENPE | c.7942C>T p.R2648* | Nonsense Mutation (SNP) | VAF 523/1419 reads (37%) | catalogued as COSV54377012; called by muse, mutect2, varscan2
- CENPE | c.2252C>A p.S751Y | Missense Mutation (SNP) | VAF 351/1071 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1385538527, COSV99478764; called by muse, mutect2, varscan2
- CENPF | c.4450A>C p.S1484R | Missense Mutation (SNP) | VAF 72/1250 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.887); catalogued as rs1269368923; called by muse, mutect2
- CENPI | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 426/555 reads (77%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs775674652, COSV99515471; called by muse, mutect2, varscan2
- CEP112 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 299/819 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752106202, COSV67136129; called by muse, mutect2, varscan2
- CEP131 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs780580407; called by muse, mutect2, varscan2
- CEP135 | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 356/946 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs140245520; called by muse, mutect2, varscan2
- CEP170 | c.3695G>A p.R1232H | Missense Mutation (SNP) | VAF 212/911 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774088718; called by muse, mutect2, varscan2
- CEP290 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 419/1136 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs1217313312; called by muse, mutect2, varscan2
- CEP295 | c.6428C>T p.P2143L | Missense Mutation (SNP) | VAF 417/1143 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199658719; called by muse, mutect2, varscan2
- CEP83 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 521/1351 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1288256034, COSV60406406; called by muse, mutect2, varscan2
- CEP89 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 182/530 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs182600896, COSV59867510; called by muse, mutect2, varscan2
- CER1 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 459/1177 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.388); catalogued as rs1459200200; called by muse, mutect2, varscan2
- CERS2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 524/953 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as rs1295903061; called by muse, mutect2, varscan2
- CERS2 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 590/1032 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as rs185209926, COSV54984944; called by muse, mutect2, varscan2
- CES2 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 276/699 reads (39%) | catalogued as rs28382815; called by muse, mutect2, varscan2
- CETN1 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 332/926 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1478884892, COSV100511374; called by muse, mutect2, varscan2
- CFAP20DC | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 300/685 reads (44%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.873); catalogued as rs1011330731; called by muse, mutect2, varscan2
- CFAP54 | c.2299G>T p.D767Y | Missense Mutation (SNP) | VAF 216/562 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.561); catalogued as COSV100127508; called by mutect2, varscan2
- CFAP57 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 345/870 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs755893459; called by muse, mutect2, varscan2
- CFAP58 | c.1443G>T p.E481D | Missense Mutation (SNP) | VAF 456/1302 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as rs1387039931, COSV100866175; called by mutect2, varscan2
- CFAP74 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 180/469 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs917431326, COSV54564663; called by muse, mutect2, varscan2
- CFAP77 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 156/418 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs761039835, COSV58012853; called by muse, mutect2, varscan2
- CFAP97 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 431/1204 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777547282, COSV71712781, COSV71712782; called by muse, mutect2, varscan2
- CFAP97 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 358/860 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs1260147449; called by muse, mutect2, varscan2
- CFAP99 | c.124C>T p.H42Y (on ENST00000506607; = p.H527Y on NM_001193282.3) | Missense Mutation (SNP) | VAF 199/513 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1016330131; called by muse, mutect2, varscan2
- CFHR3 | c.437G>A p.C146Y | Missense Mutation (SNP) | VAF 146/787 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV66402337; called by muse, mutect2, varscan2
- CH25H | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 326/816 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as rs1176428849; called by muse, mutect2, varscan2
- CHAC1 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 136/386 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.115); catalogued as rs1440627484, COSV101471060; called by muse, varscan2
- CHAMP1 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 378/1016 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs782768495, COSV63522287; called by muse, varscan2
- CHCHD2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 172/478 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as rs748182315, COSV101271042; called by muse, mutect2, varscan2
- CHD1 | c.2498G>T p.R833I | Missense Mutation (SNP) | VAF 263/789 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99033566; called by muse, mutect2, varscan2
- CHD4 | c.3560G>A p.R1187Q (on ENST00000357008 / NM_001363606.2; = p.R1200Q on NM_001273.5) | Missense Mutation (SNP) | VAF 290/658 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58898240; called by muse, mutect2, varscan2
- CHD6 | c.3403C>T p.R1135C | Missense Mutation (SNP) | VAF 323/772 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332592488, COSV58555143; called by muse, mutect2, varscan2
- CHD8 | c.4384C>T p.R1462* (on ENST00000646647 / NM_001170629.2; = p.R1183* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 274/700 reads (39%) | catalogued as rs1555314400, COSV63218773; called by muse, mutect2, varscan2
- CHERP | c.2693G>A p.R898H | Missense Mutation (SNP) | VAF 92/280 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52223845; called by muse, mutect2, varscan2
- CHERP | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 160/452 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs994398670; called by muse, varscan2
- CHERP | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 129/374 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs900864534, COSV52223105; called by muse, mutect2, varscan2
- CHIT1 | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 704/1332 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0.04); catalogued as rs747015261; called by muse, mutect2, varscan2
- CHML | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 303/1302 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs1055935839; called by muse, mutect2, varscan2
- CHMP2A | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 131/338 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs144804005; called by muse, mutect2, varscan2
- CHRDL1 | c.1243G>A p.E415K (on ENST00000372045; = p.E421K on NM_145234.4) | Missense Mutation (SNP) | VAF 283/360 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs776899237, COSV54323694; called by muse, mutect2, varscan2
- CHRFAM7A | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 197/844 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222637529, COSV100241724; called by muse, mutect2, varscan2
- CHRM3 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 690/1285 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903730617, COSV55082398; called by muse, varscan2
- CHRNA3 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 231/627 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766076436, COSV58775382; called by muse, mutect2, varscan2
- CHRNA4 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 248/587 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs772253190, COSV100937359; called by muse, varscan2
- CHRNB3 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 105/288 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1316872227, COSV51493201; called by muse, mutect2, varscan2
- CHRNB3 | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 251/716 reads (35%) | catalogued as rs757161082; called by muse, varscan2
- CHRNB4 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 110/340 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs962959008; called by muse, mutect2, varscan2
- CHRNE | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 258/628 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV53420308; called by muse, mutect2, varscan2
- CHRNE | c.47-4G>A | Splice Region (SNP) | VAF 168/439 reads (38%) | catalogued as rs767084417; called by muse, mutect2, varscan2
- CHST10 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 218/536 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs367887748, COSV51804118; called by muse, mutect2, varscan2
- CHST11 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 265/713 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759769235; called by muse, mutect2, varscan2
- CHST12 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 137/321 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs553499652, COSV51675084; called by muse, mutect2, varscan2
- CHST4 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 191/533 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as rs143449711; called by muse, mutect2, varscan2
- CHST8 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 202/542 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1261984908, COSV52857526; called by muse, varscan2
- CHSY3 | c.931G>T p.G311* | Nonsense Mutation (SNP) | VAF 347/863 reads (40%) | catalogued as COSV59272704; called by muse, mutect2, varscan2
- CHTF18 | c.2384C>T p.T795M | Missense Mutation (SNP) | VAF 139/353 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs200840110; called by muse, mutect2, varscan2
- CIB4 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 418/1198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1182817306; called by muse, mutect2, varscan2
- CIC | c.4249C>T p.R1417C | Missense Mutation (SNP) | VAF 254/662 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs778167932, COSV50549090; called by muse, mutect2, varscan2
- CIDEC | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 203/551 reads (37%) | catalogued as rs757670421, COSV100396545, COSV61062298; called by muse, mutect2, varscan2
- CIITA | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 210/579 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.149); catalogued as rs1172384411, COSV100162634; called by muse, mutect2, varscan2
- CIITA | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 380/1037 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs543712859, COSV100162296; called by muse, mutect2, varscan2
- CILP2 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1568370358; called by muse, mutect2
- CIT | c.5965C>T p.R1989W | Missense Mutation (SNP) | VAF 144/388 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs779338485; called by muse, varscan2
- CIT | c.5921G>A p.R1974H | Missense Mutation (SNP) | VAF 154/372 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1310332241, COSV55873090; called by muse, varscan2
- CLASRP | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 142/370 reads (38%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.026); catalogued as rs761623118; called by muse, mutect2, varscan2
- CLCN2 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 298/702 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.374); catalogued as rs745479097, COSV55602983; called by muse, mutect2, varscan2
- CLCN2 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 211/539 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV55600900; called by muse, mutect2, varscan2
- CLCN7 | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 156/440 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs1468307771; called by muse, mutect2, varscan2
- CLDN15 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 170/495 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs765578247; called by muse, mutect2, varscan2
- CLDN9 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 131/347 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs751354671; called by muse, mutect2, varscan2
- CLEC16A | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 115/324 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs1204178085; called by muse, mutect2, varscan2
- CLEC4D | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 299/897 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs765594498, COSV55228247; called by muse, mutect2, varscan2
- CLEC6A | c.546G>T p.W182C | Missense Mutation (SNP) | VAF 364/1014 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV101165612; called by muse, mutect2, varscan2
- CLIP2 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 150/422 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs782653077, COSV56278064; called by muse, mutect2, varscan2
- CLN8 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 260/676 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.545); catalogued as rs1285178214; called by muse, mutect2, varscan2
- CLPX | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 181/521 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770495927, COSV55647583; called by muse, mutect2, varscan2
- CLRN2 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 311/870 reads (36%) | catalogued as rs774584580, COSV101492692; called by muse, mutect2, varscan2
- CLSTN3 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 195/475 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs1468403713, COSV56938811; called by muse, mutect2, varscan2
- CLUAP1 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 248/722 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs780260970; called by muse, mutect2, varscan2
- CLUH | c.2308G>A p.V770M (on ENST00000435359; = p.V809M on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 260/664 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs368772841; called by muse, mutect2, varscan2
- CLUH | c.1123C>T p.R375W (on ENST00000435359; = p.R413W on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 212/547 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70928374; called by muse, mutect2, varscan2
- CMPK1 | c.646-1G>A p.X216_splice | Splice Site (SNP) | VAF 197/596 reads (33%) | catalogued as COSV100898590; called by muse, mutect2, varscan2
- CMTM8 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 326/892 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs752120687, COSV100282581; called by muse, mutect2, varscan2
- CMYA5 | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 650/1712 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV71405630; called by mutect2, varscan2
- CNGA4 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 338/906 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs202030466; called by muse, mutect2, varscan2
- CNN1 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 93/250 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as rs759065611; called by muse, mutect2, varscan2
- CNNM2 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 250/737 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100881947; called by muse, mutect2, varscan2
- CNNM2 | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 395/1131 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779494027; called by muse, mutect2, varscan2
- CNOT1 | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 506/1293 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV99799370; called by muse, mutect2, varscan2
- CNOT3 | c.-50C>T | Splice Region (SNP) | VAF 124/266 reads (47%) | catalogued as rs765336754; called by muse, mutect2, varscan2
- CNOT9 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 536/1440 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55301537; called by muse, mutect2, varscan2
- CNST | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 277/1055 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs373284626; called by muse, mutect2, varscan2
- CNST | c.1675A>G p.T559A | Missense Mutation (SNP) | VAF 781/1410 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs758939111; called by muse, mutect2, varscan2
- CNTN4 | c.2092C>T p.L698F | Missense Mutation (SNP) | VAF 358/925 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs866560366, COSV61881820; called by muse, mutect2, varscan2
- CNTN6 | c.2678dup p.V894Sfs*25 | Frame Shift Ins (INS) | VAF 446/1270 reads (35%) | catalogued as rs1415730148; called by mutect2, pindel, varscan2
- CNTNAP3 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 110/585 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs1385962260, COSV99905262; called by muse, mutect2, varscan2
- CNTROB | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 392/1084 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1351896198; called by muse, mutect2, varscan2
- COBL | c.3541C>T p.R1181* | Nonsense Mutation (SNP) | VAF 180/463 reads (39%) | catalogued as rs1010875572, COSV54343424; called by muse, mutect2, varscan2
- COBL | c.2591C>T p.S864F | Missense Mutation (SNP) | VAF 244/638 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99472717; called by muse, mutect2, varscan2
- COBL | c.2393C>T p.T798M | Missense Mutation (SNP) | VAF 151/424 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as rs199755175; called by muse, mutect2, varscan2
- COBLL1 | c.3241G>A p.E1081K (on ENST00000392717; = p.E1043K on NM_014900.5) | Missense Mutation (SNP) | VAF 419/1120 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1415298824, COSV52068495; called by muse, mutect2, varscan2
- COG6 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 326/896 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs147560202; ClinVar: uncertain significance; called by muse, varscan2
- COL11A2 | c.1136G>A p.R379Q (on ENST00000341947 / NM_080680.3; = p.R272Q on NM_080679.2) | Missense Mutation (SNP) | VAF 190/530 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.642); catalogued as rs150429851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL15A1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 140/386 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs754779649, COSV100897663; called by muse, mutect2, varscan2
- COL18A1 | c.3184C>T p.P1062S (on ENST00000359759 / NM_130444.3; = p.P827S on NM_030582.4) | Missense Mutation (SNP) | VAF 170/411 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs1175856480; called by muse, mutect2, varscan2
- COL1A1 | c.3649C>T p.R1217W | Missense Mutation (SNP) | VAF 286/720 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763727068, COSV56802605; called by muse, mutect2, varscan2
- COL1A2 | c.3772C>T p.R1258C | Missense Mutation (SNP) | VAF 470/1308 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766273613, COSV51965590; called by muse, mutect2, varscan2
- COL25A1 | c.298-1G>T p.X100_splice | Splice Site (SNP) | VAF 317/823 reads (39%) | catalogued as COSV101211137; called by muse, mutect2, varscan2
- COL28A1 | c.1154C>A p.P385H | Missense Mutation (SNP) | VAF 191/592 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as rs760334140; called by muse, mutect2, varscan2
- COL2A1 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 109/314 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs371440147; called by muse, mutect2, varscan2
- COL4A2 | c.3206G>A p.R1069Q | Missense Mutation (SNP) | VAF 147/432 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.273); catalogued as rs200275883, COSV100847396; called by muse, mutect2, varscan2
- COL4A3 | c.3755C>T p.A1252V | Missense Mutation (SNP) | VAF 226/678 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs761179248, COSV59257746; called by muse, mutect2, varscan2
- COL4A6 | c.4438C>T p.P1480S | Missense Mutation (SNP) | VAF 230/291 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57867370, COSV57880817; called by muse, mutect2, varscan2
- COL4A6 | c.3491C>T p.P1164L | Missense Mutation (SNP) | VAF 208/271 reads (77%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.621); catalogued as rs1438174609; called by muse, mutect2, varscan2
- COL5A1 | c.3484G>A p.G1162R | Missense Mutation (SNP) | VAF 188/492 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM128978, COSV65673925; called by muse, mutect2, varscan2
- COL5A2 | c.3572G>A p.G1191E | Missense Mutation (SNP) | VAF 284/844 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879871; called by muse, mutect2, varscan2
- COL6A1 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 121/368 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.817); catalogued as rs776914710; called by muse, mutect2, varscan2
- COL6A2 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 169/498 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs886044102; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.7062G>T p.Q2354H | Missense Mutation (SNP) | VAF 140/387 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99799095; called by muse, mutect2, varscan2
- COL6A3 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 364/1034 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs774531619, COSV55079364; called by muse, mutect2, varscan2
- COL6A5 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 384/945 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV104375315; called by muse, mutect2, varscan2
- COL7A1 | c.3932G>A p.G1311D | Missense Mutation (SNP) | VAF 212/559 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100095150; called by muse, mutect2, varscan2
- COL7A1 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 249/628 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs200570283; called by muse, mutect2, varscan2
- COMP | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 188/506 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs746239398; called by muse, mutect2, varscan2
- COP1 | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 721/1382 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs534768981; called by muse, mutect2, varscan2
- COPA | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 513/951 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292511645, COSV54100533; called by muse, mutect2, varscan2
- COPA | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 24/827 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1380526285, COSV54100553; called by muse, mutect2
- COPG1 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 188/468 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376130585; called by muse, mutect2, varscan2
- COQ8A | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 213/828 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs374860701; called by muse, mutect2, varscan2
- CORIN | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 329/860 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750996817, COSV56686834; called by muse, mutect2, varscan2
- CORO6 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 214/571 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs746798640; called by muse, mutect2, varscan2
- COX16 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 570/762 reads (75%) | catalogued as rs781059799; called by muse, mutect2, varscan2
- COX4I1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 358/456 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs779831701; called by muse, mutect2, varscan2
- COX7A1 | c.170T>C p.M57T | Missense Mutation (SNP) | VAF 199/626 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1568398569; called by muse, mutect2, varscan2
- CPA1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 232/549 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs200161199; called by muse, mutect2, varscan2
- CPA3 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 363/1042 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1480716038; called by muse, mutect2, varscan2
- CPA4 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 336/913 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs373007376, COSV99745071; called by muse, mutect2, varscan2
- CPEB1 | c.875G>A p.R292Q (on ENST00000617958; = p.R232Q on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/494 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs765510280, COSV55618907; called by muse, mutect2, varscan2
- CPHXL | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 244/703 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs529339396; called by muse, mutect2, varscan2
- CPN2 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 138/401 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV60472452; called by muse, mutect2, varscan2
- CPNE6 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 187/487 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1473044110, COSV99393760; called by muse, varscan2
- CPT1C | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 217/563 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99773688; called by muse, mutect2, varscan2
- CPT2 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 237/631 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770734793, COSV53760213; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CR1 | c.5590G>A p.V1864I | Missense Mutation (SNP) | VAF 343/1228 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as rs752517997; called by muse, varscan2
- CR2 | c.184A>C p.S62R | Missense Mutation (SNP) | VAF 936/1614 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1319331048; called by muse, mutect2, varscan2
- CRACDL | c.2259dup p.E754Rfs*53 | Frame Shift Ins (INS) | VAF 90/297 reads (30%) | catalogued as COSV67409031; called by mutect2, pindel, varscan2
- CRAMP1 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 135/400 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs749843552; called by muse, mutect2, varscan2
- CRB2 | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 153/341 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1181689936; called by muse, mutect2, varscan2
- CREB3L3 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 122/374 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs765586313; called by muse, varscan2
- CROCC | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 290/744 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1356790331; called by muse, mutect2, varscan2
- CROCC | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 150/431 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as rs761979650; called by muse, mutect2, varscan2
- CROCC2 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 257/694 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs1268126563; called by muse, mutect2, varscan2
- CRP | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 453/815 reads (56%) | SIFT tolerated (0.77); PolyPhen benign (0.024); catalogued as rs774544095, COSV54814703, COSV54814922; called by muse, mutect2, varscan2
- CRTAC1 | c.1780C>T p.R594W | Missense Mutation (SNP) | VAF 241/712 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as rs757570658, COSV54006953; called by muse, mutect2, varscan2
- CRY1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 457/1190 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs769728649, COSV50486663; called by muse, mutect2, varscan2
- CRYBB2 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 184/435 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV68005547; called by muse, mutect2, varscan2
- CRYBG2 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 110/322 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as rs772759101; called by muse, mutect2, varscan2
- CRYBG3 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 283/802 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs911852632; called by muse, mutect2
- CRYBG3 | c.4718T>C p.I1573T | Missense Mutation (SNP) | VAF 534/1414 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs560406248; called by muse, mutect2, varscan2
- CRYZ | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 251/775 reads (32%) | catalogued as rs756850761, COSV100558473; called by muse, mutect2, varscan2
- CSDE1 | c.1875C>T p.G625= (on ENST00000358528 / NM_001007553.3; = p.G594= on NM_007158.6) | Splice Region (SNP) | VAF 156/548 reads (28%) | catalogued as COSV99796087; called by muse, mutect2, varscan2
- CSDE1 | c.1807C>T p.R603C (on ENST00000358528 / NM_001007553.3; = p.R572C on NM_007158.6) | Missense Mutation (SNP) | VAF 397/1122 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as COSV54743532; called by muse, mutect2, varscan2
- CSF1 | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 163/407 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs769263389, COSV100294372; called by muse, mutect2, varscan2
- CSF1R | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 124/336 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1029057991, COSV53827975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSF2RA | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 92/217 reads (42%) | catalogued as rs753455319, CM109619, COSV62626538; called by muse, mutect2, varscan2
- CSMD1 | c.8453T>C p.F2818S (on ENST00000520002; = p.F2817S on NM_033225.6) | Missense Mutation (SNP) | VAF 381/916 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs367715641, COSV59313359; called by muse, mutect2, varscan2
- CSN2 | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 419/1072 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs544047853; called by muse, mutect2, varscan2
- CSNK2A1 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 169/553 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328131782, COSV53937807; called by muse, mutect2, varscan2
- CSPP1 | c.1337+1G>T p.X446_splice (on ENST00000676605; = p.X405_splice on NM_024790.6) | Splice Site (SNP) | VAF 316/857 reads (37%) | catalogued as COSV51589836, COSV51591540; called by muse, mutect2, varscan2
- CSPP1 | c.3533G>A p.R1178Q (on ENST00000676605; = p.R1137Q on NM_024790.6) | Missense Mutation (SNP) | VAF 401/1052 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768899319; called by muse, mutect2, varscan2
- CSRP3 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 293/770 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV56389018; called by muse, mutect2, varscan2
- CTNNA1 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 352/927 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV57079281; called by muse, mutect2, varscan2
- CTSK | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 572/1103 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs200870056; called by muse, mutect2, varscan2
- CTTNBP2 | c.1882G>A p.V628I | Missense Mutation (SNP) | VAF 319/893 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs776855094, COSV99353984; called by muse, mutect2, varscan2
- CUBN | c.9304G>A p.A3102T | Missense Mutation (SNP) | VAF 466/1313 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1385701478; called by muse, mutect2, varscan2
- CUBN | c.6784C>T p.Q2262* | Nonsense Mutation (SNP) | VAF 556/1527 reads (36%) | catalogued as rs376017039; called by muse, mutect2, varscan2
- CUBN | c.5324G>A p.R1775Q | Missense Mutation (SNP) | VAF 259/800 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.036); catalogued as rs751337888, COSV100912421; called by muse, mutect2, varscan2
- CUBN | c.4132C>T p.R1378C | Missense Mutation (SNP) | VAF 315/906 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); catalogued as rs1290293396, COSV64728057; called by muse, mutect2, varscan2
- CUL9 | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 138/448 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs150241912; called by muse, mutect2, varscan2
- CUX1 | c.2721G>T p.Q907H | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV99470008; called by muse, mutect2, varscan2
- CUX2 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 184/537 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747887990; called by muse, mutect2, varscan2
11,610 further variants in this file (6,933 protein-altering or splice-affecting, 2,378 silent, 2,299 other) are not listed here.
